Somatic mutation profile of tumor specimen 0DUUQ8 from CCDI case PBCLDA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 13.2 years (4,828 days).
Specimen 0DUUQ8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a6a5889-01e5-46a9-9083-c399e166157e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUUPM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2002224-de8c-42a6-9ad7-db89ec476b02

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'UTR 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.159_173del p.F53_Q58delinsL | In Frame Del (DEL) | VAF 84/432 reads (19%) | catalogued as COSV61072289; called by mutect2, pindel, varscan2
- ARMH3 | c.94A>T p.I32F | Missense Mutation (SNP) | VAF 41/328 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.007); called by mutect2, varscan2
- CDK18 | c.944G>T p.G315V (on ENST00000506784 / NM_212503.3; = p.G285V on NM_002596.4) | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DCHS1 | c.8297A>T p.E2766V | Missense Mutation (SNP) | VAF 52/438 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, varscan2
- FAM171B | c.688T>G p.F230V | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- MAGEE1 | c.2071C>G p.L691V | Missense Mutation (SNP) | VAF 15/459 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); called by muse, mutect2
- MAK | c.477T>G p.Y159* | Nonsense Mutation (SNP) | VAF 53/352 reads (15%) | called by muse, mutect2, varscan2
- MAPK7 | c.2155A>G p.K719E | Missense Mutation (SNP) | VAF 55/307 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- SLC6A16 | c.1243C>A p.L415I | Missense Mutation (SNP) | VAF 10/306 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); called by muse, mutect2
- RARRES1 | c.*74G>A | 3'UTR (SNP) | VAF 16/90 reads (18%) | catalogued as rs1345192166; called by mutect2, varscan2
